Surgical pathology report (de-identified scan), TCGA case TCGA-74-6575, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Swedish Neurosciences, specimen TCGA-74-6575-01A (Primary Tumor).

[page 1 of 3]
Results: PATHOLOGY / NON GYN

Status: [REDACTED]

CYTOLOGY [REDACTED]

Collection Information

Collection Date [REDACTED]

Collection Time: [REDACTED]

Lab Information

Lab [REDACTED]

TCGA - 74 - 6575

Component Results

SURGICAL PATHOLOGY
REPORT

Case Number: [REDACTED] * Updated *

Procedures/Addenda Present

Collected: [REDACTED] Received: [REDACTED]

Signed Out: [REDACTED] Reported: [REDACTED]

CLINICAL INFORMATION:

Left occipital tumor.

ICD-9 Code: 239.6 brain tumor

INTRAPROCEDURAL CONSULTATION:

B. Left occipital tumor (frozen section and touch preparations):
Glioblastoma.

GROSS DESCRIPTION:

A. Received fresh on [REDACTED] is approximately 10 cc of clear, orange, material with fluid, labeled [REDACTED] designated "A. cyst fluid left". Prepared is one cell block.

B. Received fresh, labeled [REDACTED] and designated "B. left occipital tumor", are three irregular portions of soft, friable tissue, 0.3-0.9 cm in greatest dimension. Two tissues are frozen and submitted in BFS. The third tissue is submitted in B.

C. Received in formalin, labeled [REDACTED] and designated "C. left occipital tumor", is a 1.5 x 1.5 x 0.6 cm aggregate of irregular portions of soft friable tissue with adherent hemorrhagic material, entirely submitted in cassette C. [REDACTED]

D. Received in formalin, labeled [REDACTED] and designated "D. CUSA contents", are multiple white-tan, shaggy portions of soft tissue, admixed with minimal blood clot and collectively 3.5 x 3.0 x 0.3 cm. The specimen is entirely submitted in three cassettes.

E. Received in formalin labeled, [REDACTED] and designated "E. left occipital tumor", is a 3.3 x 2.2 x 1.0 cm irregular, unoriented portion of brain matter, partially surfaced by unremarkable meninges. The resection margin is irregular and is inked blue. The specimen is serially sectioned to reveal a 0.5 x 0.4 x 0.4 cm poorly-defined tan-grey possible lesion, which comes to within 0.1 cm from the resection margin. A photograph is taken and the specimen is entirely submitted sequentially in five cassettes with lesion in E1 and E2. [REDACTED]

MICROSCOPIC DESCRIPTION:

The immunohistochemical tests reported were developed and performance characteristics determined by [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests may be used for clinical purposes. They should not be regarded as

[page 2 of 3]
[REDACTED]

investigational or for research use only. [REDACTED] is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical laboratory testing.

FINAL PATHOLOGIC DIAGNOSIS:

A. LEFT OCCIPITAL CYST FLUID, INCLUDING EVALUATION OF CELL BLOCK:

-Proteinaceous fluid with fragments of high-grade glioma.

B. LEFT OCCIPITAL TUMOR, BIOPSIES:

C. LEFT OCCIPITAL TUMOR, RESECTION:

D. CUSA CONTENTS:

E. LEFT OCCIPITAL TUMOR, RESECTION:

Glioblastoma, WHO grade IV/IV, with the following features:

-Degree of cellularity: high.

-Microvascular proliferation: present.

-Necrosis: present.

-Mitotic rate: 5 per 10 HPFs.

-Other features: FISH, MGMT (by PCR and immunohistochemistry) and p53 are pending.

Electronically Signed By

PROCEDURES/ADDENDA:

FISH Date Ordered: [REDACTED] Status: [REDACTED]

Date Complete: [REDACTED] By: [REDACTED]

Date Reported: [REDACTED]

Interpretation

B. Brain, left occipital tumor, FISH results:

-Negative for a 1p/19q codeletion.

-Positive for polysomy 1 and 19.

-Positive for polysomy 7/EGFR.

-Negative for monosomy/deletion PTEN.

Results-Comments

At the request of [REDACTED] representative sections of the tumor (block B1) were submitted for FISH analysis. The results are consistent with glioblastoma. Please see separate report by [REDACTED]

ICC- IMMUNOHISTOCHEMISTRY Date Ordered: [REDACTED] Status:

Date Complete: [REDACTED]

Date Reported: [REDACTED]

By: [REDACTED]

Interpretation

B. Left occipital tumor biopsies, immunohistochemistry results:

-Tumor is regionally positive for p53.

-Tumor is positive for MGMT (approximately 90% of tumor).

[page 3 of 3]
Encounter Date: [REDACTED]

Results-Comments

At the request of [REDACTED], representative sections of the tumor (block B1) were submitted for p53 and MGMT analysis by immunohistochemistry. The immunohistochemical tests reported were developed and performance characteristics determined by [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests may be used for clinical purposes. They should not be regarded as investigational or for research use only. [REDACTED] is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical laboratory testing.

TISSUE SENDOUT Date Ordered: [REDACTED] Status: [REDACTED]
Date Complete: [REDACTED] By: [REDACTED]
Date Reported: [REDACTED]

Interpretation

C. Left occipital tumor, MGMT methylation studies:
-Gene methylation not detected.

Results-Comments

Representative sections of the tumor (block C1) were submitted for MGMT methylation studies by PCR. The result is gene methylation not detected. Please see separate report by [REDACTED]

UPDATES:

Amended: [REDACTED]

Reason: Add Procedure Results
CELL BLOCK WAS REVIEWED

Previous Signout Date: [REDACTED]

Amended: [REDACTED]

Reason: Additional Tissue Submitted
PARTS D & E REC'D IN HISTO ON [REDACTED]

Previous Signout Date: [REDACTED]

[Lab Inquiry](#)

[View Complete Results](#)

[Reviewed by List](#)

Order Details

[Order Details](#)

Source: NCI Genomic Data Commons file 861ba58b-4764-4876-a1fb-1c494569767f (TCGA-74-6575.5ECEDD86-01D1-40C8-896F-1566E6D2DFFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).